Somatic mutation profile of tumor specimen TCGA-DI-A1BU-01A (aliquot TCGA-DI-A1BU-01A-11D-A135-09) from TCGA case TCGA-DI-A1BU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 55.1 years (20,114 days).
Specimen TCGA-DI-A1BU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44384b27-60c8-4308-adbd-24b2111e80b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DI-A1BU-10A (Blood Derived Normal), aliquot TCGA-DI-A1BU-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e774b1d6-a4c5-4f02-a1d9-ee9b96cc4fd2

The open-access MAF lists 9,568 somatic variants for this specimen: 6,983 protein-altering or splice-affecting, 2,360 silent, 225 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5,882, Silent 2,360, Frame Shift Del 532, Splice Site 183, Nonsense Mutation 132, Frame Shift Ins 125, Splice Region 92, Intron 91, RNA 63, 3'UTR 26, 5'Flank 20, In Frame Del 17.

Variants (750 of 9,568; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG6 | c.634dup p.C212Lfs*9 | Frame Shift Ins (INS) | VAF 28/112 reads (25%) | catalogued as rs879133727; ClinVar: likely pathogenic; called by mutect2, varscan2
- ALMS1 | c.10822C>T p.R3608* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as rs1192396248, CM074692, COSV100041495; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 20/34 reads (59%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 28/107 reads (26%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 33/137 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- CACNA1A | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1064794263, CM065992, COSV64194216, COSV64200368; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CLMP | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as rs765907815, COSV101507384; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A1 | c.2263G>A p.G755R | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs672601346, CM099131, COSV65420631; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL7A1 | c.6081del p.P2029Lfs*177 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs780623622, CD961934; ClinVar: pathogenic; called by mutect2, varscan2
- CSPP1 | c.2831del p.N944Mfs*2 (on ENST00000676605; = p.N903Mfs*2 on NM_024790.6) | Frame Shift Del (DEL) | VAF 20/90 reads (22%) | catalogued as rs863225190, COSV51582895; ClinVar: pathogenic; called by mutect2, varscan2
- DCDC2 | c.529del p.I177Sfs*3 | Frame Shift Del (DEL) | VAF 27/86 reads (31%) | catalogued as rs904944428; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DSG2 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs121913006, CM061700, COSV99852889; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- EP300 | c.4026-2A>G p.X1342_splice | Splice Site (SNP) | VAF 46/133 reads (35%) | catalogued as rs1555911098, COSV99607715; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EVC2 | c.816+2T>C p.X272_splice | Splice Site (SNP) | VAF 25/83 reads (30%) | catalogued as rs1294715119, COSV100185289; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGA | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909606, CM100506, CM930249, COSV57393361; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLCN | c.1285dup p.H429Pfs*27 | Frame Shift Ins (INS) | VAF 16/52 reads (31%) | catalogued as rs80338682; ClinVar: pathogenic; called by mutect2, varscan2
- HNF1A | c.864del p.P291Qfs*51 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs762703502, CM1412341, CX035684, COSV104379772; ClinVar: pathogenic; called by mutect2, varscan2
- KMT2B | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as rs1057519283, COSV99385902; ClinVar: likely pathogenic; called by muse, varscan2
- LDLR | c.187T>C p.C63R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879254426, CM014573, COSV99369660; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MYO3A | c.2180del p.N727Ifs*32 | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | catalogued as rs769462859; ClinVar: likely pathogenic; called by mutect2, varscan2
- MYO7A | c.1623dup p.K542Qfs*5 | Frame Shift Ins (INS) | VAF 17/59 reads (29%) | catalogued as rs782077721; ClinVar: pathogenic; called by mutect2, varscan2
- PAH | c.110T>C p.L37P | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs869312996, CM1314660, COSV100187727; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SACS | c.3328del p.I1110Lfs*16 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | catalogued as rs770866403; ClinVar: likely pathogenic; called by mutect2, varscan2
- SEC63 | c.1605del p.K535Nfs*28 | Frame Shift Del (DEL) | VAF 28/104 reads (27%) | catalogued as rs752868449; ClinVar: pathogenic; called by mutect2, varscan2
- SETD5 | c.3783dup p.F1262Lfs*61 | Frame Shift Ins (INS) | VAF 25/61 reads (41%) | catalogued as rs1553641424; ClinVar: pathogenic; called by mutect2, varscan2
- SMARCA4 | c.2143G>A p.D715N | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1131691371, COSV60790098; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SPINK5 | c.2468del p.K823Rfs*101 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs565782662; ClinVar: pathogenic; called by mutect2, varscan2
- STAT5B | c.1102dup p.Q368Pfs*9 | Frame Shift Ins (INS) | VAF 20/79 reads (25%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.216del p.V73Wfs*50 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | catalogued as rs730882018; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TRIM44 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); catalogued as rs886039241, CM1512224, COSV100194807; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TSC1 | c.1257del p.R420Gfs*20 | Frame Shift Del (DEL) | VAF 29/94 reads (31%) | catalogued as rs118203506, CD991903; ClinVar: not provided / pathogenic; called by mutect2, pindel, varscan2
- USH2A | c.8890del p.W2964Gfs*10 | Frame Shift Del (DEL) | VAF 22/77 reads (29%) | catalogued as rs786205116; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A1CF | c.1704A>C p.Q568H (on ENST00000373993 / NM_138932.2; = p.Q560H on NM_014576.4) | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99255448; called by muse, mutect2, varscan2
- AACS | c.904C>T p.H302Y | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99907838; called by muse, mutect2, varscan2
- AADACL2 | c.253A>G p.T85A | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100735704; called by muse, mutect2, varscan2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 23/64 reads (36%) | catalogued as rs746497630; called by mutect2, varscan2
- AADACL4 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.055); catalogued as COSV100879367; called by muse, mutect2, varscan2
- AAK1 | c.2868T>A p.D956E | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101296178; called by muse, mutect2, varscan2
- AAMDC | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546888173, COSV100489886; called by muse, mutect2, varscan2
- AAMP | c.1142T>C p.I381T | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs568215295, COSV99946217; called by muse, mutect2, varscan2
- AAR2 | c.242T>C p.L81P | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV100299179; called by muse, mutect2, varscan2
- ABCA1 | c.2548T>C p.Y850H | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.408); catalogued as COSV101036637; called by muse, mutect2, varscan2
- ABCA12 | c.5937C>A p.A1979= (on ENST00000272895 / NM_173076.3; = p.A1661= on NM_015657.3) | Splice Region (SNP) | VAF 15/75 reads (20%) | catalogued as rs1360924681, COSV99788798; called by muse, mutect2, varscan2
- ABCA12 | c.416T>C p.V139A | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as COSV99788802; called by muse, mutect2, varscan2
- ABCA13 | c.11251A>T p.T3751S | Missense Mutation (SNP) | VAF 72/205 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV101446860, COSV71286088; called by muse, mutect2, varscan2
- ABCA13 | c.12802A>T p.T4268S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.059); catalogued as COSV101291217; called by muse, mutect2, varscan2
- ABCA2 | c.5885A>G p.D1962G (on ENST00000614293; = p.D1932G on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV55798722; called by muse, mutect2, varscan2
- ABCA2 | c.1794G>A p.W598* (on ENST00000614293; = p.W568* on NM_001606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 47/145 reads (32%) | catalogued as COSV99687100; called by muse, mutect2, varscan2
- ABCA3 | c.3823A>G p.T1275A | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.101); catalogued as COSV100068138; called by muse, mutect2
- ABCA3 | c.1388A>G p.Y463C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100068141; called by muse, mutect2, varscan2
- ABCA4 | c.5045T>A p.V1682D | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100933053; called by muse, mutect2, varscan2
- ABCA5 | c.3616A>G p.R1206G | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs535300608, COSV101201032; called by muse, mutect2, varscan2
- ABCA6 | c.3175T>C p.C1059R | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV99445988; called by muse, varscan2
- ABCA6 | c.428A>G p.Y143C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV99445990; called by muse, mutect2
- ABCA8 | c.2124T>A p.Y708* | Nonsense Mutation (SNP) | VAF 29/99 reads (29%) | catalogued as COSV99285094; called by muse, mutect2, varscan2
- ABCA8 | c.594G>T p.M198I | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.314); catalogued as COSV52208866, COSV99285098; called by muse, mutect2, varscan2
- ABCA9 | c.3706C>T p.P1236S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100382759; called by muse, mutect2, varscan2
- ABCB4 | c.2020T>C p.S674P | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV99709887; called by muse, mutect2, varscan2
- ABCB6 | c.520T>C p.W174R | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99521647; called by muse, mutect2, varscan2
- ABCB8 | c.778C>T p.Q260* (on ENST00000297504 / NM_001282291.2; = p.Q243* on NM_007188.5) | Nonsense Mutation (SNP) | VAF 27/87 reads (31%) | catalogued as COSV52502583; called by muse, mutect2, varscan2
- ABCC10 | c.3558G>T p.L1186F (on ENST00000372530 / NM_001198934.2; = p.L1158F on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99766851; called by muse, mutect2, varscan2
- ABCC10 | c.4136del p.G1379Afs*56 (on ENST00000372530 / NM_001198934.2; = p.G1351Afs*56 on NM_033450.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 41/126 reads (33%) | catalogued as COSV99767396; called by pindel, varscan2
- ABCC11 | c.2706+1G>A p.X902_splice | Splice Site (SNP) | VAF 24/81 reads (30%) | catalogued as rs201541604, COSV100750597; called by muse, mutect2, varscan2
- ABCC11 | c.1063T>A p.Y355N | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100750599, COSV100751262; called by muse, mutect2, varscan2
- ABCC11 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs755116860, COSV62322148; called by muse, mutect2, varscan2
- ABCC2 | c.3803C>T p.A1268V | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV100966424; called by muse, mutect2, varscan2
- ABCC3 | c.48C>A p.D16E | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV99558825; called by muse, mutect2, varscan2
- ABCC4 | c.2252G>A p.G751E | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV100972313; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCC6 | c.1193G>A p.S398N | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.21); catalogued as COSV99228261; called by muse, mutect2, varscan2
- ABCC8 | c.3242C>T p.T1081M | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs764005234, COSV100216782; called by muse, mutect2, varscan2
- ABCC9 | c.3922C>T p.Q1308* | Nonsense Mutation (SNP) | VAF 25/75 reads (33%) | catalogued as COSV99684875; called by muse, mutect2, varscan2
- ABCC9 | c.926T>C p.L309S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99684877; called by muse, mutect2, varscan2
- ABCD1 | c.1323G>T p.E441D | Missense Mutation (SNP) | VAF 71/178 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV99497319; called by muse, mutect2, varscan2
- ABCD1 | c.1708G>A p.G570S | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV99497321; called by muse, mutect2, varscan2
- ABCD3 | c.143A>G p.N48S | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs373581476; called by muse, mutect2, varscan2
- ABCF3 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs1012680356, COSV53055628; called by muse, mutect2, varscan2
- ABCG1 | c.165del p.V56* | Frame Shift Del (DEL) | VAF 18/77 reads (23%) | catalogued as rs1426985067; called by mutect2, pindel, varscan2
- ABHD12 | c.508A>G p.I170V | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100194257; called by muse, mutect2, varscan2
- ABHD14B | c.453+2T>C p.X151_splice | Splice Site (SNP) | VAF 25/93 reads (27%) | catalogued as rs765061080, COSV100258954; called by muse, mutect2, varscan2
- ABHD16A | c.1565A>T p.D522V | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as COSV101013132; called by muse, mutect2, varscan2
- ABHD16A | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs756797641, COSV101013133; called by muse, mutect2, varscan2
- ABHD16B | c.1378C>A p.P460T | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV99410556; called by muse, mutect2, varscan2
- ABHD17A | c.491C>A p.A164D (on ENST00000292577 / NM_001130111.2; = p.A215D on NM_031213.4) | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99171221; called by muse, mutect2, varscan2
- ABHD4 | c.724A>G p.I242V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as COSV99360470; called by muse, mutect2, varscan2
- ABI3 | c.241dup p.A81Gfs*207 | Frame Shift Ins (INS) | VAF 8/31 reads (26%) | catalogued as rs1316149275; called by mutect2, varscan2
- ABI3 | c.377C>G p.A126G | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV99865328; called by muse, mutect2, varscan2
- ABLIM1 | c.1034A>G p.K345R | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs774893980, COSV99521599; called by muse, varscan2
- ABLIM3 | c.661G>C p.V221L | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.318); catalogued as COSV100448133; called by muse, mutect2, varscan2
- ABLIM3 | c.2005G>T p.A669S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1294692941, COSV58641619, COSV58648759; called by muse, mutect2, varscan2
- ABRA | c.1048A>T p.I350F | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100357493; called by muse, mutect2, varscan2
- ABRAXAS2 | c.677A>G p.D226G | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100044866; called by muse, mutect2, varscan2
- ABTB1 | c.806A>G p.N269S (on ENST00000232744 / NM_172027.3; = p.N127S on NM_032548.3) | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV99229639; called by muse, mutect2, varscan2
- AC011455.2 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1288258671, COSV99671165; called by muse, mutect2, varscan2
- AC018630.4 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 43/91 reads (47%) | catalogued as COSV99958490; called by muse, mutect2, varscan2
- AC068580.4 | c.941C>A p.A314D | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99362260; called by muse, mutect2, varscan2
- AC092143.1 | c.1618G>A p.V540M | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100205664; called by muse, mutect2, varscan2
- AC092143.1 | c.2354A>G p.E785G | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.813); catalogued as COSV100205665; called by muse, mutect2, varscan2
- AC104452.1 | c.623A>G p.D208G | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99864438; called by muse, varscan2
- AC118470.1 | c.*38-2A>G | Splice Site (SNP) | VAF 7/65 reads (11%) | catalogued as COSV100129013; called by muse, mutect2
- ACACB | c.754A>G p.T252A | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV100622458; called by muse, varscan2
- ACACB | c.3901T>C p.Y1301H | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100622460; called by muse, mutect2, varscan2
- ACAD8 | c.934A>G p.N312D | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV99844138; called by muse, varscan2
- ACADL | c.602A>G p.K201R | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99284588; called by muse, mutect2
- ACADL | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV99284590; called by muse, mutect2, varscan2
- ACADSB | c.1231A>G p.T411A | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0.012); catalogued as COSV100715104; called by muse, mutect2
- ACAN | c.2239A>G p.T747A | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.121); catalogued as COSV100717337; called by muse, mutect2, varscan2
- ACAP2 | c.1391T>C p.L464S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100461632; called by muse, mutect2, varscan2
- ACAP2 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as rs1168274084, COSV100461634; called by muse, mutect2, varscan2
- ACE | c.818T>C p.L273P | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as COSV99326556; called by muse, mutect2, varscan2
- ACKR4 | c.461G>A p.C154Y | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as COSV99391699; called by muse, mutect2, varscan2
- ACOT11 | c.473T>C p.V158A | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.802); catalogued as COSV100650517; called by muse, mutect2, varscan2
- ACOT4 | c.326T>C p.L109P | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100412812; called by muse, mutect2, varscan2
- ACOX1 | c.1625A>G p.K542R | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV99503365; called by muse, mutect2, varscan2
- ACOX2 | c.530A>G p.E177G | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100250033; called by muse, mutect2, varscan2
- ACOX3 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.378); catalogued as rs767609868, COSV100711838; called by muse, mutect2, varscan2
- ACR | c.392A>G p.H131R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181641366, COSV99334378; called by muse, mutect2, varscan2
- ACSBG2 | c.1578del p.I527Ffs*19 | Frame Shift Del (DEL) | VAF 42/130 reads (32%) | catalogued as rs754308951, COSV53122693; called by mutect2, pindel, varscan2
- ACSL1 | c.1589T>C p.L530S | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99860428; called by muse, mutect2, varscan2
- ACTL6A | c.244A>G p.M82V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1485325951, COSV101199637; called by muse, varscan2
- ACTL7A | c.892A>G p.T298A | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV100453052; called by muse, mutect2, varscan2
- ACTL7B | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs765347719, COSV101012499; called by muse, mutect2, varscan2
- ACTL9 | c.637A>G p.N213D | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as COSV100185173; called by muse, mutect2, varscan2
- ACTN1 | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as COSV99517430; called by muse, mutect2, varscan2
- ACTN2 | c.1663A>T p.I555F | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV100856598; called by muse, mutect2, varscan2
- ACTN3 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.729); catalogued as rs1290257280, COSV101557814; called by muse, mutect2, varscan2
- ACTN3 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100074151; called by muse, mutect2, varscan2
- ACTN4 | c.364A>G p.K122E | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV99399849; called by muse, mutect2, varscan2
- ACTN4 | c.1936T>A p.S646T | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99399852; called by muse, mutect2, varscan2
- ACTR2 | c.758A>C p.K253T | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.89); PolyPhen benign (0.263); catalogued as rs956981513, COSV99573746; called by muse, mutect2, varscan2
- ACTR8 | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99213614; called by muse, mutect2, varscan2
- ACVR1 | c.643+2T>C p.X215_splice | Splice Site (SNP) | VAF 14/35 reads (40%) | catalogued as COSV55118605, COSV55122229; called by muse, mutect2, varscan2
- ACVR2B | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as rs957188913, COSV100754180; called by muse, mutect2, varscan2
- ADAM15 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.696); catalogued as rs745498420, COSV55062072; called by muse, mutect2, varscan2
- ADAM18 | c.167A>T p.Y56F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.654); catalogued as COSV99695067; called by mutect2, varscan2
- ADAM18 | c.421T>C p.Y141H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99695069; called by muse, mutect2, varscan2
- ADAM19 | c.776G>A p.G259D | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99976396; called by muse, mutect2, varscan2
- ADAM19 | c.666+1G>A p.X222_splice | Splice Site (SNP) | VAF 19/63 reads (30%) | catalogued as COSV99976400; called by muse, mutect2, varscan2
- ADAM2 | c.1193G>A p.C398Y | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771452813, COSV99696911; called by muse, mutect2, varscan2
- ADAM20 | c.706A>T p.N236Y | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.92); PolyPhen benign (0.051); catalogued as COSV99833360; called by muse, mutect2
- ADAM20 | c.35T>C p.V12A | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV99833361; called by muse, mutect2
- ADAM22 | c.2001G>C p.R667S | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as COSV55973369, COSV99716096; called by muse, mutect2, varscan2
- ADAM23 | c.1948T>C p.C650R | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100006973; called by muse, mutect2, varscan2
- ADAM30 | c.848T>C p.V283A | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as rs1557795224, COSV101023781; called by muse, mutect2, varscan2
- ADAM32 | c.1733T>C p.V578A | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.516); catalogued as COSV101165295; called by muse, mutect2, varscan2
- ADAM33 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 23/91 reads (25%) | catalogued as COSV100597729; called by muse, mutect2, varscan2
- ADAM7 | c.156+2T>C p.X52_splice | Splice Site (SNP) | VAF 21/76 reads (28%) | catalogued as COSV99443222; called by muse, mutect2, varscan2
- ADAMTS10 | c.788A>G p.Y263C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV99546575; called by muse, mutect2, varscan2
- ADAMTS12 | c.2918A>G p.K973R | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.115); catalogued as COSV100710423; called by muse, mutect2, varscan2
- ADAMTS13 | c.2651G>T p.W884L | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100746994; called by muse, mutect2, varscan2
- ADAMTS15 | c.1544T>C p.V515A | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV100143160; called by muse, mutect2
- ADAMTS15 | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.072); catalogued as COSV100143162; called by muse, mutect2
- ADAMTS15 | c.1742A>G p.E581G | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs764019858, COSV100143164; called by muse, mutect2, varscan2
- ADAMTS16 | c.2795C>T p.S932F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.964); catalogued as rs1466520997, COSV99940403; called by muse, mutect2, varscan2
- ADAMTS19 | c.2667G>A p.V889= | Splice Region (SNP) | VAF 35/119 reads (29%) | catalogued as COSV99176548; called by muse, mutect2, varscan2
- ADAMTS2 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99201112; called by muse, mutect2, varscan2
- ADAMTS2 | c.634T>C p.Y212H | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99201114; called by muse, mutect2, varscan2
- ADAMTS20 | c.5477T>C p.F1826S | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as COSV101239030; called by muse, mutect2, varscan2
- ADAMTS20 | c.3709T>C p.Y1237H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as COSV101166098; called by muse, mutect2, varscan2
- ADAMTS20 | c.3099C>T p.C1033= | Splice Region (SNP) | VAF 16/56 reads (29%) | catalogued as rs766363508, COSV101166101; called by muse, mutect2, varscan2
- ADAMTS20 | c.1941C>T p.G647= | Splice Region (SNP) | VAF 9/43 reads (21%) | catalogued as COSV67134046; called by muse, mutect2, varscan2
- ADAMTS3 | c.2846A>G p.Y949C | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV99710430; called by muse, mutect2, varscan2
- ADAMTS7 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 104/282 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1158478134, COSV101183035; called by muse, mutect2, varscan2
- ADAMTSL1 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99441401; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1267A>G p.T423A | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.224); catalogued as COSV99441414; called by muse, mutect2, varscan2
- ADAMTSL2 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100618926, COSV100619026; called by muse, mutect2, varscan2
- ADAMTSL3 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99717444; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3310A>G p.S1104G | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99717448; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3880A>G p.T1294A | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.429); catalogued as COSV99717451; called by muse, mutect2, varscan2
- ADAMTSL5 | c.1225G>A p.V409M | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs751869733, COSV100389080; called by muse, varscan2
- ADAT1 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1464193866, COSV100329128; called by muse, mutect2, varscan2
- ADCK2 | c.641T>C p.V214A | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99301437; called by muse, mutect2, varscan2
- ADCY1 | c.2494G>A p.D832N | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.208); catalogued as COSV99811462; called by muse, mutect2, varscan2
- ADCY10 | c.3832G>A p.A1278T | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV100896641; called by muse, mutect2, varscan2
- ADCY10 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100896642; called by muse, mutect2, varscan2
- ADCY2 | c.304T>C p.F102L | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100602061; called by muse, mutect2, varscan2
- ADCY2 | c.918C>A p.C306* | Nonsense Mutation (SNP) | VAF 24/51 reads (47%) | catalogued as COSV100602062; called by muse, mutect2, varscan2
- ADCY2 | c.1597C>T p.H533Y | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100602065, COSV57886318; called by muse, mutect2
- ADCY2 | c.1925T>C p.I642T | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.097); catalogued as rs1432612525, COSV100602067, COSV100603961; called by muse, mutect2, varscan2
- ADCY5 | c.2944A>G p.T982A | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs564846157, COSV100567410; called by muse, varscan2
- ADCY5 | c.1019A>G p.Y340C | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101518397; called by muse, mutect2, varscan2
- ADCY7 | c.2632G>A p.V878I | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs747007427, COSV99575753; called by muse, mutect2, varscan2
- ADCY9 | c.3598A>G p.T1200A | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.331); catalogued as COSV99569540; called by muse, mutect2, varscan2
- ADD1 | c.854T>C p.L285S | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.044); catalogued as rs997117092, COSV99296109; called by muse, mutect2, varscan2
- ADGRA2 | c.1774C>T p.L592F | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV100177632; called by muse, varscan2
- ADGRA3 | c.3302A>G p.K1101R | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as COSV99293018; called by muse, mutect2, varscan2
- ADGRA3 | c.824T>C p.V275A | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV99293025; called by muse, mutect2, varscan2
- ADGRA3 | c.536T>C p.L179S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51561339; called by muse, varscan2
- ADGRB1 | c.2063A>G p.D688G | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100029333; called by muse, mutect2, varscan2
- ADGRE2 | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100215769; called by muse, mutect2, varscan2
- ADGRE2 | c.659A>G p.Q220R | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1256396531, COSV100215774; called by muse, mutect2, varscan2
- ADGRE5 | c.1036C>T p.P346S (on ENST00000242786 / NM_078481.4; = p.P253S on NM_001784.5) | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.097); catalogued as COSV99662711; called by muse, mutect2, varscan2
- ADGRF2 | c.1360C>A p.L454M (on ENST00000296862 / NM_001368115.2; = p.L386M on NM_153839.7) | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99730855; called by muse, mutect2, varscan2
- ADGRF3 | c.2099G>A p.G700E (on ENST00000311519 / NM_001145168.1; = p.G501E on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV100274836; called by muse, mutect2, varscan2
- ADGRG4 | c.4882G>A p.A1628T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs369286267, COSV99794678; called by muse, mutect2, varscan2
- ADGRG4 | c.8882G>A p.G2961E | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234045804, COSV99794682; called by muse, mutect2, varscan2
- ADGRG5 | c.608del p.G203Afs*62 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | catalogued as rs750862917; called by mutect2, pindel, varscan2
- ADGRG6 | c.68T>C p.L23S | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as COSV99746200; called by muse, varscan2
- ADGRG6 | c.1076A>G p.Y359C | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV99746206; called by muse, varscan2
- ADGRL1 | c.3337C>T p.R1113C (on ENST00000340736 / NM_001008701.3; = p.R1108C on NM_014921.5) | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778374913, COSV61564705; called by muse, mutect2, varscan2
- ADGRL1 | c.2079G>T p.Q693H (on ENST00000340736 / NM_001008701.3; = p.Q688H on NM_014921.5) | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as COSV100529325; called by muse, mutect2, varscan2
- ADGRL1 | c.1781T>C p.I594T (on ENST00000340736 / NM_001008701.3; = p.I589T on NM_014921.5) | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as COSV100529327; called by muse, mutect2, varscan2
- ADGRL1 | c.928T>C p.Y310H (on ENST00000340736 / NM_001008701.3; = p.Y305H on NM_014921.5) | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.58); catalogued as COSV100529328; called by muse, mutect2, varscan2
- ADGRL3 | c.2168G>A p.R723K (on ENST00000506720 / NM_001322402.2; = p.R655K on NM_015236.6) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.05); catalogued as COSV101546910; called by muse, mutect2
- ADGRL3 | c.3701A>G p.Y1234C (on ENST00000506720 / NM_001322402.2; = p.Y1166C on NM_015236.6) | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101546912; called by muse, mutect2, varscan2
- ADGRV1 | c.3141_3142del p.D1051Ffs*5 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | catalogued as rs1450569413; called by mutect2, varscan2
- ADGRV1 | c.8584T>C p.Y2862H | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101315588; called by muse, mutect2, varscan2
- ADGRV1 | c.9716G>A p.W3239* | Nonsense Mutation (SNP) | VAF 39/116 reads (34%) | catalogued as COSV101315589; called by muse, mutect2, varscan2
- ADGRV1 | c.10237T>C p.F3413L | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.908); catalogued as COSV101315590; called by muse, mutect2, varscan2
- ADH1C | c.446A>G p.Q149R | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs766776134, COSV101565165; called by muse, mutect2, varscan2
- ADI1 | c.472T>C p.Y158H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as rs1477866618, COSV100537720; called by muse, mutect2, varscan2
- ADNP | c.3065A>G p.D1022G | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.173); catalogued as rs1470174108, COSV100823661; called by muse, mutect2, varscan2
- ADNP | c.1061A>G p.N354S | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs866056890, COSV100823662; called by muse, mutect2, varscan2
- ADNP | c.365A>G p.E122G | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.986); catalogued as COSV100823663; called by muse, mutect2, varscan2
- ADPRHL1 | c.788G>T p.W263L | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.751); catalogued as COSV100733379; called by muse, mutect2, varscan2
- ADPRM | c.833A>G p.H278R | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100541351; called by muse, mutect2, varscan2
- ADRA2A | c.631T>C p.Y211H | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99701505; called by muse, mutect2, varscan2
- AEBP1 | c.2383del p.E795Rfs*32 | Frame Shift Del (DEL) | VAF 18/83 reads (22%) | catalogued as COSV56260153; called by mutect2, pindel, varscan2
- AFAP1 | c.1079G>A p.S360N | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as COSV100631241; called by muse, varscan2
- AFAP1 | c.973A>G p.T325A | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV100631242; called by muse, mutect2, varscan2
- AFF1 | c.2005A>G p.K669E | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as rs771164837, COSV100320264; called by muse, mutect2, varscan2
- AFF1 | c.2963C>T p.A988V | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100320265; called by muse, mutect2, varscan2
- AFF2 | c.1510A>G p.T504A | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV99662399; called by muse, mutect2, varscan2
- AFF3 | c.2086G>A p.V696M | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.708); catalogued as rs1481879079, COSV100418150; called by muse, mutect2, varscan2
- AFF3 | c.1900A>G p.R634G | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV100418151; called by muse, mutect2, varscan2
- AFMID | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV100014849; called by muse, mutect2, varscan2
- AFMID | c.623A>G p.N208S | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100014851; called by muse, mutect2, varscan2
- AGAP1 | c.1672A>G p.I558V (on ENST00000304032 / NM_001037131.3; = p.I505V on NM_014914.5) | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.941); catalogued as COSV100364017; called by muse, mutect2, varscan2
- AGAP1 | c.1936G>A p.E646K (on ENST00000304032 / NM_001037131.3; = p.E593K on NM_014914.5) | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs376727493; called by muse, mutect2, varscan2
- AGAP1 | c.2264G>A p.G755D (on ENST00000304032 / NM_001037131.3; = p.G702D on NM_014914.5) | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100364021; called by muse, mutect2, varscan2
- AGAP2 | c.3119A>G p.Q1040R (on ENST00000547588 / NM_001122772.2; = p.Q684R on NM_014770.4) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.273); catalogued as COSV57731851, COSV99222463; called by muse, mutect2, varscan2
- AGAP4 | c.1072A>G p.I358V | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.097); catalogued as COSV101432622; called by muse, mutect2, varscan2
- AGAP6 | c.464+2T>C p.X155_splice (on ENST00000374056 / NM_001365867.1; = p.X178_splice on NM_001077665.2) | Splice Site (SNP) | VAF 39/392 reads (10%) | catalogued as COSV100929052; called by muse, mutect2, varscan2
- AGAP6 | c.1991A>G p.*664Wext*50 (on ENST00000374056 / NM_001365867.1; = p.*687Wext*50 on NM_001077665.2) | Nonstop Mutation (SNP) | VAF 35/164 reads (21%) | catalogued as rs1385174523, COSV100929054; called by muse, mutect2, varscan2
- AGBL1 | c.182T>C p.V61A | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.769); catalogued as COSV101407933; called by muse, mutect2, varscan2
- AGGF1 | c.1419T>A p.D473E | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100461594; called by muse, mutect2, varscan2
- AGO1 | c.803C>T p.T268I | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV100940773; called by muse, mutect2, varscan2
- AGO1 | c.2063C>T p.A688V | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100940774; called by muse, mutect2, varscan2
- AGO4 | c.1435G>A p.G479S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100942809; called by muse, mutect2, varscan2
- AGO4 | c.1639A>G p.T547A | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as COSV100942812; called by muse, mutect2, varscan2
- AGPAT3 | c.32T>C p.F11S | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.279); catalogued as COSV99377237; called by muse, mutect2, varscan2
- AGRN | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.525); catalogued as COSV101038648; called by muse, varscan2
- AGRN | c.5306C>T p.P1769L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101038649; called by muse, mutect2
- AGRN | c.5792G>A p.S1931N | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.187); catalogued as COSV101038651; called by muse, mutect2, varscan2
- AGXT2 | c.1060A>G p.N354D | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99183721; called by muse, mutect2, varscan2
- AGXT2 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99183722; called by muse, mutect2, varscan2
- AHCTF1 | c.6598A>G p.T2200A (on ENST00000366508; = p.T2174A on NM_015446.5) | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1386883939, COSV100403268; called by muse, varscan2
- AHCTF1 | c.5291G>A p.S1764N (on ENST00000366508; = p.S1738N on NM_015446.5) | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV100403270; called by muse, mutect2, varscan2
- AHCTF1 | c.3499T>A p.S1167T (on ENST00000366508; = p.S1141T on NM_015446.5) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV100403273; called by muse, mutect2, varscan2
- AHCTF1 | c.1481T>C p.V494A (on ENST00000366508; = p.V468A on NM_015446.5) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.218); catalogued as COSV100403274; called by muse, mutect2, varscan2
- AHCY | c.205A>G p.T69A | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99464074; called by muse, varscan2
- AHDC1 | c.3823C>T p.R1275W | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1306069724, COSV99898989; called by muse, mutect2, varscan2
- AHNAK | c.11599A>G p.N3867D | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.333); catalogued as COSV99946092; called by muse, mutect2, varscan2
- AHNAK | c.4546C>A p.P1516T | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99945748, COSV99946093; called by muse, mutect2, varscan2
- AHNAK2 | c.16460T>C p.F5487S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV60918013; called by muse, mutect2, varscan2
- AIDA | c.646A>G p.T216A | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100388103; called by muse, mutect2, varscan2
- AK9 | c.5071T>C p.Y1691H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101413943; called by muse, mutect2, varscan2
- AK9 | c.3461A>G p.Q1154R | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV100393320; called by muse, mutect2, varscan2
- AKAP10 | c.1366G>T p.V456F | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV56732874, COSV99855306; called by muse, mutect2, varscan2
- AKAP13 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100773231; called by muse, mutect2, varscan2
- AKAP13 | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV100773234; called by muse, mutect2, varscan2
- AKAP17A | c.515A>T p.D172V | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100001965, COSV100002147; called by muse, mutect2, varscan2
- AKAP6 | c.3137A>G p.E1046G | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99799063; called by muse, mutect2, varscan2
- AKAP8 | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99511773; called by muse, mutect2, varscan2
- AKAP9 | c.7017+2T>C p.X2339_splice (on ENST00000359028; = p.X2315_splice on NM_005751.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 11/23 reads (48%) | catalogued as COSV100662064; called by muse, mutect2, varscan2
- AKR1B15 | c.324G>T p.W108C | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101423352, COSV71152664; called by muse, mutect2
- AKR1C4 | c.592A>G p.N198D | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99578542; called by muse, mutect2, varscan2
- AKT1S1 | c.542C>T p.A181V (on ENST00000344175 / NM_001098633.4; = p.A201V on NM_032375.5) | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100464962; called by muse, mutect2, varscan2
- AKT2 | c.153del p.L52* | Frame Shift Del (DEL) | VAF 39/137 reads (28%) | catalogued as COSV100251670; called by mutect2, pindel, varscan2
- AKTIP | c.599T>C p.V200A | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.089); catalogued as COSV50878054; called by muse, mutect2, varscan2
- AL121899.2 | c.155G>T p.R52L | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101198409, COSV67351415; called by muse, mutect2, varscan2
- AL133500.1 | c.1294A>G p.K432E | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated, low confidence (0.15); catalogued as COSV99860281; called by muse, mutect2, varscan2
- AL133500.1 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated, low confidence (0.26); catalogued as rs1310006723, COSV55744332; called by muse, mutect2, varscan2
- AL136295.1 | c.2381G>A p.G794D | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV55779191; called by muse, mutect2, varscan2
- AL592490.1 | c.1256T>C p.V419A | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV101308123; called by muse, mutect2, varscan2
- ALAS1 | c.1322G>A p.G441E | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100050229; called by muse, mutect2, varscan2
- ALCAM | c.304A>G p.N102D | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.652); catalogued as COSV100064397; called by muse, mutect2
- ALCAM | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as rs371053542; called by muse, mutect2, varscan2
- ALDH16A1 | c.581G>A p.C194Y | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs1161174008, COSV99512664; called by muse, mutect2
- ALDH18A1 | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV100973081; called by muse, mutect2, varscan2
- ALDH18A1 | c.235A>G p.S79G | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100973085; called by muse, mutect2, varscan2
- ALDH1A3 | c.751A>G p.N251D | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100320268; called by muse, mutect2, varscan2
- ALDH1B1 | c.704T>C p.V235A | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs966425990, COSV100890897; called by muse, mutect2
- ALDH3B1 | c.938A>C p.D313A | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.217); catalogued as COSV99141722; called by muse, varscan2
- ALDH4A1 | c.1366T>C p.Y456H | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV51890926; called by muse, mutect2, varscan2
- ALDH6A1 | c.1588A>G p.M530V | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV100620827; called by muse, mutect2, varscan2
- ALDH6A1 | c.1250A>G p.E417G | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100620828; called by muse, mutect2, varscan2
- ALDH8A1 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV99664511; called by muse, varscan2
- ALDOA | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.325); catalogued as rs549434187, COSV100581967; called by muse, mutect2, varscan2
- ALG10 | c.1196T>G p.F399C | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99847961, COSV99848245; called by muse, mutect2, varscan2
- ALG10B | c.353T>C p.V118A | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV100439820; called by muse, mutect2, varscan2
- ALG12 | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 31/90 reads (34%) | PolyPhen benign (0.006); catalogued as COSV100427032; called by muse, mutect2, varscan2
- ALG13 | c.2267C>T p.T756I | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.43); catalogued as rs772050498, COSV99321791; called by muse, mutect2, varscan2
- ALG14 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 39/101 reads (39%) | catalogued as rs769920583, COSV100930832; called by muse, mutect2, varscan2
- ALG3 | c.1256A>G p.Q419R | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.135); catalogued as COSV99890877; called by muse, varscan2
- ALK | c.1597A>G p.T533A | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as COSV66581203; called by muse, mutect2, varscan2
- ALKAL1 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV100660110; called by muse, mutect2, varscan2
- ALMS1 | c.3047A>G p.E1016G | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.205); catalogued as COSV100041483; called by muse, mutect2, varscan2
- ALMS1 | c.3181C>T p.P1061S | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs754651123, COSV100041486; called by muse, mutect2, varscan2
- ALOX12 | c.529A>G p.T177A | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV99277923; called by muse, mutect2, varscan2
- ALOX12 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.8); PolyPhen benign (0.013); catalogued as COSV99277926; called by muse, mutect2, varscan2
- ALOXE3 | c.1415G>A p.G472D | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs138290721; called by muse, mutect2, varscan2
- ALPI | c.1406A>G p.H469R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs772481331, COSV99785734; called by muse, mutect2, varscan2
- ALPK2 | c.3295T>C p.S1099P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100864190; called by muse, mutect2, varscan2
- ALPK3 | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.3); catalogued as COSV99360387; called by muse, mutect2, varscan2
- ALPK3 | c.2550G>A p.M850I | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV51935221; called by muse, mutect2, varscan2
- ALS2 | c.59T>C p.V20A | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99968919; called by muse, mutect2, varscan2
- ALS2CL | c.2674T>C p.S892P | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV100014827; called by muse, mutect2, varscan2
- ALS2CL | c.992G>A p.G331D | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1170220450, COSV100014830; called by muse, mutect2, varscan2
- AMBRA1 | c.1409G>T p.R470M (on ENST00000458649 / NM_001367468.1; = p.R380M on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV100093069; called by muse, mutect2, varscan2
- AMER1 | c.1783G>A p.A595T | Missense Mutation (SNP) | VAF 66/225 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs149055969, COSV57662894; called by muse, mutect2, varscan2
- AMER2 | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.668); catalogued as rs372051684, COSV100766162; called by muse, mutect2, varscan2
- AMFR | c.965T>C p.M322T | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs1382723707, COSV99315692; called by muse, mutect2, varscan2
- AMFR | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.459); catalogued as COSV99315697; called by muse, mutect2, varscan2
- AMMECR1 | c.290T>A p.L97H | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.439); catalogued as COSV99466382; called by muse, mutect2, varscan2
- AMPD1 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs548608037, COSV100814902; called by muse, mutect2, varscan2
- AMPD1 | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.827); catalogued as rs1232219627, COSV100814904; called by muse, varscan2
- AMPD2 | c.112del p.A38Pfs*95 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as rs1403470706; called by mutect2, pindel, varscan2
- AMTN | c.133A>G p.N45D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.295); catalogued as rs368417913; called by muse, varscan2
- AMY2B | c.724A>G p.K242E | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV100796215; called by muse, mutect2, varscan2
- AMZ1 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs201858896, COSV100406206; called by muse, varscan2
- AMZ2 | c.285C>A p.G95= | Splice Region (SNP) | VAF 21/58 reads (36%) | catalogued as COSV100703119; called by muse, mutect2, varscan2
- ANAPC1 | c.2419T>C p.Y807H | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV100594568; called by muse, mutect2, varscan2
- ANAPC1 | c.2035A>G p.R679G | Missense Mutation (SNP) | VAF 67/236 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs771137582, COSV100594569; called by muse, mutect2, varscan2
- ANAPC2 | c.923G>A p.G308D | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV100118940; called by muse, mutect2, varscan2
- ANAPC4 | c.235+1G>A p.X79_splice | Splice Site (SNP) | VAF 8/35 reads (23%) | catalogued as rs770288432, COSV100193869; called by muse, varscan2
- ANAPC4 | c.524T>C p.I175T | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV100193871; called by muse, mutect2, varscan2
- ANAPC4 | c.1907A>G p.Y636C | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100193874; called by muse, mutect2, varscan2
- ANGPT2 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.18); catalogued as rs760458544, COSV57337388; called by muse, varscan2
- ANGPT2 | c.1093A>G p.N365D | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV100290706; called by muse, varscan2
- ANGPT2 | c.217T>C p.Y73H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.535); catalogued as COSV100290707; called by muse, mutect2, varscan2
- ANGPTL2 | c.806A>G p.D269G | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.035); catalogued as COSV99401078; called by muse, mutect2, varscan2
- ANK1 | c.1159A>G p.M387V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.145); catalogued as rs773497101, COSV99224324; called by muse, mutect2, varscan2
- ANK1 | c.131A>G p.N44S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV99224327; called by muse, mutect2, varscan2
- ANK3 | c.11188A>G p.T3730A | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.07); catalogued as COSV99778776; called by muse, mutect2, varscan2
- ANK3 | c.1880C>T p.A627V | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.478); catalogued as COSV99778781; called by muse, mutect2, varscan2
- ANK3 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.114); catalogued as COSV99778784; called by muse, mutect2, varscan2
- ANKAR | c.3077A>G p.Q1026R | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs546856067, COSV99853965; called by muse, mutect2, varscan2
- ANKEF1 | c.655C>T p.H219Y | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.09); catalogued as COSV101000995; called by muse, mutect2, varscan2
- ANKFN1 | c.1918G>A p.V640M | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as rs763328804, COSV100593921, COSV59453373, COSV59462313; called by muse, mutect2, varscan2
- ANKIB1 | c.427A>G p.N143D | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.288); catalogued as COSV99728568; called by muse, mutect2, varscan2
- ANKLE2 | c.1934A>G p.D645G | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100513972; called by muse, mutect2, varscan2
- ANKRD11 | c.7729T>C p.S2577P | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99968553; called by muse, varscan2
- ANKRD11 | c.4645A>G p.S1549G | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99968554; called by muse, mutect2, varscan2
- ANKRD12 | c.1201A>G p.K401E | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100040918; called by muse, mutect2, varscan2
- ANKRD13B | c.1627T>C p.S543P | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100801152; called by muse, mutect2, varscan2
- ANKRD13C | c.990A>T p.L330F | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); catalogued as COSV99256376; called by muse, mutect2, varscan2
- ANKRD13C | c.766A>T p.I256F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as COSV99256380; called by muse, mutect2, varscan2
- ANKRD17 | c.3581G>A p.G1194D | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100428678; called by muse, mutect2, varscan2
- ANKRD17 | c.1984A>G p.N662D | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.262); catalogued as COSV100428680, COSV58224862; called by muse, mutect2, varscan2
- ANKRD30A | c.2020G>A p.E674K (on ENST00000611781; = p.E618K on NM_052997.2) | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.678); catalogued as COSV64617755; called by muse, mutect2, varscan2
- ANKRD30A | c.4055T>C p.I1352T (on ENST00000611781; = p.I1296T on NM_052997.2) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs930357367, COSV100653068; called by muse, mutect2, varscan2
- ANKRD34A | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100041173; called by muse, mutect2, varscan2
- ANKRD35 | c.1451G>A p.G484D | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.059); catalogued as rs1559173678, COSV100841652; called by muse, mutect2, varscan2
- ANKRD50 | c.3974A>G p.E1325G | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.021); catalogued as COSV101538900; called by muse, mutect2
- ANKRD50 | c.1984A>G p.N662D | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.569); catalogued as COSV101538902; called by muse, mutect2, varscan2
- ANKRD50 | c.1600A>G p.N534D | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.339); catalogued as COSV101538903; called by muse, mutect2, varscan2
- ANKRD52 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV57287616; called by muse, mutect2, varscan2
- ANKRD54 | c.719A>G p.Q240R | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV99316388; called by muse, mutect2
- ANKRD55 | c.1591G>A p.V531M | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.082); catalogued as rs376277413, COSV100591131; called by muse, mutect2, varscan2
- ANKRD6 | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs368972696; called by muse, varscan2
- ANKS1A | c.959del p.P320Hfs*25 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | catalogued as COSV64461548; called by mutect2, pindel, varscan2
- ANKS1A | c.2784G>A p.W928* | Nonsense Mutation (SNP) | VAF 31/87 reads (36%) | catalogued as COSV100832151; called by muse, mutect2, varscan2
- ANKS6 | c.1672A>G p.I558V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.952); catalogued as COSV100782233; called by muse, mutect2, varscan2
- ANKS6 | c.1124T>A p.I375N | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100782235; called by muse, varscan2
- ANLN | c.2531T>C p.V844A | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99732003; called by muse, mutect2, varscan2
- ANO1 | c.509A>G p.E170G | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100303749; called by muse, mutect2, varscan2
- ANO5 | c.646A>G p.I216V | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as COSV100201527; called by muse, mutect2, varscan2
- ANO5 | c.886T>C p.Y296H | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100201529; called by muse, varscan2
- ANO5 | c.1537A>G p.T513A | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100201531; called by muse, mutect2, varscan2
- ANO6 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769902129, COSV57657690; called by muse, mutect2, varscan2
- ANO6 | c.1936A>G p.T646A | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV57670586; called by muse, mutect2, varscan2
- ANO7 | c.1847A>G p.Y616C (on ENST00000274979; = p.Y562C on NM_001370694.2) | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1465661605, COSV99237698; called by muse, mutect2, varscan2
- ANO7 | c.2285T>C p.I762T (on ENST00000274979; = p.I708T on NM_001370694.2) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV99237705, COSV99238176; called by muse, varscan2
- ANO9 | c.1058T>A p.V353D | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100240803; called by muse, mutect2, varscan2
- ANPEP | c.811A>G p.T271A | Missense Mutation (SNP) | VAF 81/251 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.155); catalogued as COSV100262744; called by muse, varscan2
- ANPEP | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755534306, COSV100262747; called by muse, varscan2
- ANTXR1 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100362041; called by muse, mutect2, varscan2
- ANTXR1 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.998); catalogued as rs778487700, COSV58010465, COSV58020941; called by muse, mutect2, varscan2
- ANTXR1 | c.827A>G p.D276G | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as COSV100362042; called by muse, mutect2, varscan2
- ANXA11 | c.1328C>A p.A443D | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1000931056, COSV99626903; called by muse, mutect2, varscan2
- ANXA13 | c.422A>T p.K141I | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.41); catalogued as COSV99146049; called by muse, varscan2
- AOAH | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99332314; called by muse, mutect2, varscan2
- AOC1 | c.1940C>A p.P647H | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV100710655; called by muse, mutect2, varscan2
- AOC2 | c.2101C>T p.L701F (on ENST00000253799 / NM_009590.4; = p.L674F on NM_001158.5) | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99520011; called by muse, varscan2
- AOX1 | c.460T>C p.Y154H | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101021810; called by muse, mutect2, varscan2
- AP002748.5 | c.1030A>G p.T344A | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as COSV100567750; called by muse, mutect2, varscan2
- AP1AR | c.514A>G p.R172G | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV99914093; called by muse, mutect2, varscan2
- AP1B1 | c.950T>C p.L317P | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58018453; called by muse, mutect2, varscan2
- AP1B1 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100434433; called by muse, mutect2, varscan2
- AP1G1 | c.740T>C p.V247A | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100250135; called by muse, mutect2, varscan2
- AP1G2 | c.1040A>G p.H347R | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99846100; called by muse, mutect2, varscan2
- AP1M1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); catalogued as COSV99358237; called by muse, mutect2, varscan2
- AP1M1 | c.1231T>C p.Y411H | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99358240; called by muse, mutect2, varscan2
- AP1S2 | c.311T>C p.F104S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100236605; called by muse, mutect2, varscan2
- AP2A1 | c.403A>G p.I135V | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.901); catalogued as COSV100756160; called by muse, mutect2, varscan2
- AP2A1 | c.1424T>C p.V475A | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV100756161; called by muse, mutect2, varscan2
- AP2A1 | c.2363T>C p.F788S | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100571036; called by muse, mutect2, varscan2
- AP2B1 | c.1274A>G p.Y425C | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99250957; called by muse, mutect2, varscan2
- AP2M1 | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.397); catalogued as COSV99490422; called by muse, mutect2, varscan2
- AP3B1 | c.3133T>C p.F1045L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as COSV99670873; called by muse, mutect2, varscan2
- AP3B1 | c.865A>G p.K289E | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.173); catalogued as COSV99670879; called by muse, mutect2, varscan2
- AP3B1 | c.451A>G p.M151V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.086); catalogued as COSV99670881; called by muse, mutect2, varscan2
- AP4B1 | c.1202T>C p.V401A | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99870631; called by muse, mutect2, varscan2
- AP5M1 | c.858T>A p.D286E | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.077); catalogued as COSV99841083; called by muse, mutect2, varscan2
- AP5Z1 | c.789A>G p.T263= | Splice Region (SNP) | VAF 20/46 reads (43%) | catalogued as COSV100804026; called by muse, mutect2
- AP5Z1 | c.2327G>A p.S776N | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100804028; called by muse, mutect2, varscan2
- APBA1 | c.2401del p.H801Tfs*17 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | catalogued as COSV55228718, COSV99596038; called by mutect2, varscan2
- APBB1IP | c.377A>G p.D126G | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.09); catalogued as rs1346186156, COSV100774320; called by muse, varscan2
- APBB3 | c.692G>A p.C231Y (on ENST00000357560 / NM_133173.2; = p.C238Y on NM_006051.3) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs764762969, COSV100021204; called by muse, mutect2, varscan2
- APC | c.4572A>G p.I1524M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV99965962; called by muse, mutect2, varscan2
- APEH | c.1226G>A p.S409N | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.202); catalogued as COSV99610588; called by muse, mutect2, varscan2
- APLNR | c.239T>C p.V80A | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.336); catalogued as COSV57241990; called by muse, varscan2
- APLP1 | c.565C>T p.H189Y | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.958); catalogued as rs1244427534, COSV99697555; called by muse, mutect2, varscan2
- APLP2 | c.1046A>G p.N349S | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs372001669; called by muse, mutect2, varscan2
- APOA2 | c.301T>C p.*101Rext*21 | Nonstop Mutation (SNP) | VAF 42/128 reads (33%) | catalogued as CM011279, CM032545, CM064978, COSV99248116; called by muse, varscan2
- APOA2 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV57154184; called by muse, varscan2
- APOA2 | c.113T>C p.F38S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); catalogued as COSV99248118; called by muse, mutect2, varscan2
- APOA5 | c.353T>C p.V118A | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99911204; called by muse, mutect2, varscan2
- APOB | c.13472A>G p.Y4491C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as COSV99264191; called by mutect2, varscan2
- APOB | c.12112A>G p.I4038V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.938); catalogued as rs1443981616, COSV51958933, COSV99264193; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.9707A>G p.E3236G | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV99264196; called by muse, mutect2, varscan2
- APOH | c.269T>C p.L90S | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1189396256, COSV99235610; called by muse, mutect2
- APOH | c.164A>G p.Y55C | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs748283658, COSV99235612; called by muse, mutect2, varscan2
- APOL2 | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99969070; called by muse, mutect2
- APOL2 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as rs757083546, COSV50772484; called by muse, mutect2, varscan2
- APPL1 | c.737C>A p.T246N | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs749260036, COSV99897475; called by muse, mutect2, varscan2
- APPL2 | c.1152+2T>A p.X384_splice | Splice Site (SNP) | VAF 21/80 reads (26%) | catalogued as COSV99314501; called by muse, mutect2, varscan2
- APRT | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99242950; called by muse, mutect2, varscan2
- AQP12A | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV61836880; called by muse, mutect2, varscan2
- AQP12B | c.247A>G p.T83A (on ENST00000621682; = p.T95A on NM_001102467.2) | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV101315847; called by muse, mutect2, varscan2
- AQP7 | c.278T>C p.M93T | Missense Mutation (SNP) | VAF 50/199 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs1243127641, COSV53015456, COSV99952295; called by muse, mutect2, varscan2
- AQR | c.4073T>A p.M1358K | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99333401; called by muse, mutect2, varscan2
- ARAP1 | c.2227A>G p.T743A (on ENST00000393609 / NM_001040118.2; = p.T498A on NM_015242.4) | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV100501650; called by muse, mutect2, varscan2
- ARAP2 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.317); catalogued as COSV58284138; called by muse, varscan2
- ARCN1 | c.1439A>G p.N480S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs782514712, COSV99873495; called by muse, mutect2, varscan2
- ARF1 | c.232T>C p.W78R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99683079; called by muse, mutect2, varscan2
- ARFGAP2 | c.1529T>C p.V510A | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99561767; called by muse, mutect2, varscan2
- ARFGAP2 | c.878A>G p.Q293R | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.037); catalogued as COSV100125439; called by muse, mutect2, varscan2
- ARFGEF1 | c.5038T>C p.F1680L | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0.084); catalogued as COSV99141334; called by muse, mutect2, varscan2
- ARFGEF1 | c.2993C>T p.A998V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99141335; called by muse, varscan2
- ARFGEF3 | c.49T>C p.Y17H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs200871295, COSV99292664; called by muse, varscan2
- ARFGEF3 | c.5361C>G p.S1787R | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99292668; called by muse, mutect2
- ARHGAP10 | c.2084C>T p.T695I | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as COSV100330975; called by muse, mutect2, varscan2
- ARHGAP10 | c.2240T>C p.L747S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100330978; called by muse, mutect2, varscan2
- ARHGAP11A | c.2744C>T p.A915V | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV100276696; called by muse, mutect2, varscan2
- ARHGAP12 | c.125T>C p.L42S | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60964989; called by muse, mutect2, varscan2
- ARHGAP17 | c.2338G>A p.A780T (on ENST00000289968 / NM_001006634.3; = p.A702T on NM_018054.6) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV99253013; called by muse, mutect2, varscan2
- ARHGAP21 | c.991C>A p.H331N | Missense Mutation (SNP) | VAF 64/209 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as rs771132140, COSV100255885; called by muse, mutect2, varscan2
- ARHGAP22 | c.1784G>T p.R595L | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as COSV50963896, COSV50988110; called by muse, mutect2, varscan2
- ARHGAP25 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 68/213 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs775215112, COSV54910538; called by muse, mutect2, varscan2
- ARHGAP26 | c.312+2T>C p.X104_splice | Splice Site (SNP) | VAF 31/113 reads (27%) | catalogued as COSV99189512; called by muse, mutect2, varscan2
- ARHGAP27 | c.2206G>A p.G736R (on ENST00000428638 / NM_001282290.1; = p.G395R on NM_199282.3) | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100976463, COSV100976573; called by muse, mutect2, varscan2
- ARHGAP28 | c.1958T>C p.V653A (on ENST00000383472 / NM_001366230.1; = p.V494A on NM_001010000.3) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV99148860; called by muse, mutect2, varscan2
- ARHGAP31 | c.1922A>G p.E641G | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV99956708; called by muse, mutect2
- ARHGAP31 | c.4232T>G p.I1411S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99956710; called by muse, mutect2
- ARHGAP32 | c.2767A>G p.I923V (on ENST00000310343 / NM_001378025.1; = p.I574V on NM_014715.4) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100087167; called by muse, mutect2, varscan2
- ARHGAP33 | c.823A>G p.T275A | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.164); catalogued as COSV99137672; called by muse, mutect2
- ARHGAP33 | c.1763del p.G588Afs*44 | Frame Shift Del (DEL) | VAF 6/55 reads (11%) | catalogued as rs1185494642; called by mutect2, pindel, varscan2
- ARHGAP5 | c.4442T>C p.L1481S (on ENST00000345122 / NM_001030055.2; = p.L1480S on NM_001173.3) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.986); catalogued as COSV99391918; called by muse, mutect2
- ARHGAP9 | c.533C>A p.T178K | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100712345; called by muse, mutect2, varscan2
- ARHGEF10L | c.1993G>A p.V665M | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866671024, COSV51427329; called by muse, mutect2, varscan2
- ARHGEF10L | c.3781G>C p.A1261P | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV99392200; called by muse, mutect2, varscan2
- ARHGEF11 | c.2830G>A p.A944T | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs779758499, COSV100168347; called by muse, mutect2, varscan2
- ARHGEF12 | c.595A>G p.N199D | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); catalogued as COSV100754726; called by muse, mutect2, varscan2
- ARHGEF12 | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as COSV100754728; called by muse, mutect2, varscan2
- ARHGEF12 | c.3425T>G p.I1142S | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV100754732; called by muse, mutect2, varscan2
- ARHGEF12 | c.3776T>C p.L1259S | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100754733; called by muse, varscan2
- ARHGEF15 | c.1478G>A p.C493Y | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100729998; called by muse, mutect2, varscan2
- ARHGEF17 | c.3610G>A p.D1204N | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV55237986; called by muse, mutect2, varscan2
- ARHGEF2 | c.1820T>C p.L607P (on ENST00000361247 / NM_001162383.2; = p.L579P on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100560160; called by muse, mutect2, varscan2
- ARHGEF26 | c.749T>C p.I250T | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV100726426; called by muse, mutect2, varscan2
- ARHGEF37 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 25/67 reads (37%) | catalogued as rs531304012, COSV61368932; called by muse, mutect2, varscan2
- ARHGEF38 | c.275T>C p.M92T | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV99486106; called by muse, mutect2, varscan2
- ARHGEF40 | c.3217G>T p.G1073C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.662); catalogued as COSV100070126; called by muse, mutect2, varscan2
- ARHGEF6 | c.161A>G p.E54G | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99166376; called by muse, mutect2, varscan2
- ARHGEF7 | c.698T>C p.F233S (on ENST00000375741 / NM_001113511.2; = p.F55S on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99521146; called by muse, mutect2, varscan2
- ARHGEF7 | c.2396T>C p.I799T (on ENST00000375741 / NM_001113511.2; = p.I778T on NM_145735.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV99521154; called by muse, mutect2, varscan2
- ARHGEF9 | c.9+2T>C p.X3_splice | Splice Site (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99491474; called by muse, mutect2, varscan2
- ARID1A | c.2582C>T p.A861V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.024); catalogued as rs748245175, COSV100250630; called by muse, varscan2
- ARID1B | c.3658A>G p.T1220A | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV99267750; called by muse, mutect2, varscan2
- ARID1B | c.6333C>A p.N2111K | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.6); catalogued as COSV99267755; called by muse, mutect2, varscan2
- ARID2 | c.1832A>G p.Y611C | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100535603; called by muse, mutect2, varscan2
- ARID3C | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs150189522; called by muse, mutect2, varscan2
- ARID4A | c.1534A>G p.K512E | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); catalogued as COSV100794085; called by muse, varscan2
- ARID4B | c.2063A>G p.K688R | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.952); catalogued as rs140967551; called by muse, mutect2, varscan2
- ARIH2 | c.110A>G p.D37G | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100711231; called by muse, mutect2, varscan2
- ARL14EP | c.191A>G p.Y64C | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV99955851; called by muse, mutect2, varscan2
- ARL15 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.223); catalogued as COSV101544766; called by muse, mutect2, varscan2
- ARL4D | c.237dup p.Q80Afs*28 | Frame Shift Ins (INS) | VAF 25/92 reads (27%) | catalogued as rs758198899; called by mutect2, pindel, varscan2
- ARL6IP1 | c.242A>T p.D81V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100435802; called by muse, mutect2, varscan2
- ARMC3 | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99957635; called by muse, mutect2, varscan2
- ARMC6 | c.1090A>G p.I364V (on ENST00000392336; = p.I339V on NM_033415.4) | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.101); catalogued as rs1462611005, COSV99522955; called by muse, mutect2, varscan2
- ARMC9 | c.782T>A p.I261N | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV100589554; called by muse, mutect2, varscan2
- ARMCX2 | c.1411A>G p.K471E | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.72); catalogued as COSV100168067; called by muse, mutect2, varscan2
- ARMH3 | c.1273A>G p.M425V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as COSV100898830; called by muse, mutect2, varscan2
- ARMH4 | c.671A>G p.K224R | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV99957785; called by muse, mutect2, varscan2
- ARNT2 | c.1022A>G p.H341R | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100308695, COSV57581671; called by muse, mutect2, varscan2
- ARNTL2 | c.1516T>A p.S506T | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.418); catalogued as COSV99667582; called by muse, mutect2, varscan2
- ARPC2 | c.191A>G p.Y64C | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99826591; called by muse, mutect2, varscan2
- ARRB2 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 22/68 reads (32%) | catalogued as COSV99346959; called by muse, mutect2, varscan2
- ARSA | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs765558965, COSV99332292; called by muse, mutect2, varscan2
- ARSD | c.734A>G p.Y245C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.336); catalogued as COSV54201295; called by muse, mutect2, varscan2
- ARSD | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs757015438, COSV54198845; called by muse, mutect2, varscan2
- ARSF | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100839446; called by muse, mutect2, varscan2
- ARSH | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.423); catalogued as rs1569123411, COSV101139771; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | catalogued as rs753865255; called by mutect2, varscan2
- ARSK | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV101187524; called by muse, mutect2, varscan2
- ART4 | c.16A>G p.N6D | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.476); catalogued as rs1226853596, COSV99966838; called by muse, mutect2, varscan2
- ARTN | c.112G>A p.E38K (on ENST00000372354; = p.E46K on NM_057090.2) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.746); catalogued as COSV99495037; called by muse, mutect2, varscan2
- ARVCF | c.2362T>C p.S788P | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as COSV99258396; called by muse, mutect2, varscan2
- AS3MT | c.818T>C p.V273A | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as rs1238646346, COSV100185604; called by muse, mutect2
- ASAP1 | c.2918C>T p.P973L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100726933; called by muse, mutect2, varscan2
- ASAP2 | c.1657G>T p.A553S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1558380563, COSV99855899; called by muse, mutect2, varscan2
- ASB1 | c.157C>A p.L53I | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as COSV99223153; called by muse, mutect2, varscan2
- ASB14 | c.1012T>C p.F338L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV101274091; called by muse, mutect2, varscan2
- ASB17 | c.838T>C p.S280P | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as rs1370110994, COSV99407839; called by muse, mutect2, varscan2
- ASB2 | c.1100T>C p.L367P | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100279247; called by muse, mutect2, varscan2
- ASCL1 | c.461T>C p.M154T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99901916; called by muse, mutect2, varscan2
- ASF1B | c.356A>G p.N119S | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV54615777; called by muse, varscan2
- ASF1B | c.335A>G p.Y112C | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99654241; called by muse, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | catalogued as rs761154268; called by mutect2, varscan2
- ASMT | c.871C>T p.R291* (on ENST00000381229; = p.R319* on NM_004043.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 38/118 reads (32%) | catalogued as rs768791548, CM077878, COSV101172422; called by muse, mutect2, varscan2
- ASMTL | c.359G>A p.S120N | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV101187707; called by muse, varscan2
- ASNS | c.1476+2T>C p.X492_splice | Splice Site (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99446035; called by muse, mutect2, varscan2
- ASPG | c.1429G>A p.G477S | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.983); catalogued as rs1329953939, COSV101496358; called by muse, mutect2, varscan2
- ASS1 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV100752543; called by muse, varscan2
- ASTN1 | c.3486T>A p.N1162K | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100705679; called by muse, mutect2, varscan2
- ASTN1 | c.911A>G p.N304S | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.01); catalogued as COSV99920757; called by muse, mutect2, varscan2
- ASTN2 | c.3062G>A p.G1021D (on ENST00000313400 / NM_001365069.1; = p.G970D on NM_014010.5) | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99940395; called by muse, mutect2, varscan2
- ASTN2 | c.1201T>C p.S401P (on ENST00000313400 / NM_001365069.1; = p.S350P on NM_014010.5) | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); catalogued as COSV100525360; called by muse, varscan2
- ASXL3 | c.3388C>T p.P1130S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.641); catalogued as COSV99323819; called by muse, mutect2, varscan2
- ASXL3 | c.6740T>C p.V2247A | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99323822; called by muse, mutect2, varscan2
- ATAD1 | c.871A>G p.T291A | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as COSV100058029; called by muse, mutect2, varscan2
- ATAD1 | c.651G>A p.M217I | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100058031; called by muse, mutect2, varscan2
- ATAD2B | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 32/111 reads (29%) | catalogued as COSV53194985; called by muse, mutect2, varscan2
- ATAD3A | c.1034T>C p.L345P | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV100186158; called by muse, mutect2, varscan2
- ATAD3A | c.1832A>G p.Q611R | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100186160; called by muse, mutect2, varscan2
- ATAD3B | c.283-1G>T p.X95_splice (on ENST00000308647; = p.X149_splice on NM_031921.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 56/168 reads (33%) | catalogued as COSV100426324; called by muse, mutect2, varscan2
- ATAD5 | c.3046T>C p.Y1016H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.188); catalogued as COSV100429733; called by muse, mutect2, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | catalogued as rs768611141; called by mutect2, pindel, varscan2
- ATF7IP | c.1619A>G p.E540G | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.037); catalogued as COSV99661316; called by muse, mutect2
- ATF7IP2 | c.763A>G p.S255G | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs568486230, COSV100202540; called by muse, mutect2, varscan2
- ATG16L2 | c.938A>G p.Y313C | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.662); catalogued as COSV100352207; called by muse, mutect2, varscan2
- ATG2B | c.5954A>G p.Q1985R | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99951966; called by muse, mutect2
- ATG2B | c.4430T>A p.I1477N | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.049); catalogued as COSV99951968; called by muse, mutect2, varscan2
- ATG2B | c.3410C>T p.S1137L | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV99951970; called by muse, mutect2, varscan2
- ATG2B | c.2146A>G p.N716D | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.985); catalogued as COSV100737775; called by muse, mutect2, varscan2
- ATG4B | c.428A>G p.Y143C | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV100728600; called by muse, mutect2, varscan2
- ATG4B | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99994697; called by muse, mutect2, varscan2
- ATG9B | c.293del p.P98Qfs*8 | Frame Shift Del (DEL) | VAF 15/68 reads (22%) | catalogued as rs770350293; called by mutect2, pindel, varscan2
- ATIC | c.1490G>A p.G497E | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as COSV99377556; called by muse, mutect2, varscan2
- ATMIN | c.2102A>G p.D701G | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100214546; called by muse, mutect2, varscan2
- ATN1 | c.1180T>C p.S394P | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.229); catalogued as COSV100755702; called by muse, mutect2, varscan2
- ATP13A1 | c.2641C>T p.L881F | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV99179120; called by muse, mutect2
- ATP13A1 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1336800641, COSV99365765; called by muse, mutect2, varscan2
- ATP13A3 | c.890T>A p.I297N | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99756484; called by muse, mutect2, varscan2
- ATP1A4 | c.182C>T p.T61I | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100927456; called by muse, mutect2, varscan2
- ATP1B3 | c.676T>C p.Y226H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99657183; called by muse, varscan2
- ATP2A1 | c.1712del p.P571Rfs*21 | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | catalogued as rs772363145; called by mutect2, pindel, varscan2
- ATP2A2 | c.1790G>A p.G597D | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100428456; called by muse, mutect2, varscan2
- ATP2A3 | c.872G>A p.G291D | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV59233959, COSV99988889; called by muse, mutect2, varscan2
- ATP2B1 | c.687A>G p.I229M | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as COSV99665301; called by muse, mutect2, varscan2
- ATP2B2 | c.1102C>T p.H368Y (on ENST00000352432; = p.H334Y on NM_001683.5) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.492); catalogued as COSV100659782; called by muse, mutect2, varscan2
- ATP2C1 | c.1847T>C p.V616A | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100146371; called by muse, mutect2, varscan2
- ATP4B | c.558C>T p.I186= | Splice Region (SNP) | VAF 48/117 reads (41%) | catalogued as rs372348110; called by muse, mutect2, varscan2
- ATP6V0A4 | c.665T>C p.F222S | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100022787; called by muse, varscan2
- ATP6V0A4 | c.574A>T p.I192F | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV100022789; called by muse, mutect2, varscan2
- ATP6V1B2 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52354861; called by muse, mutect2, varscan2
- ATP6V1B2 | c.689T>C p.V230A | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV99369278; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1266+2T>C p.X422_splice | Splice Site (SNP) | VAF 35/108 reads (32%) | catalogued as COSV99369281; called by muse, mutect2, varscan2
- ATP8A2 | c.2966T>C p.L989S | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.087); catalogued as COSV99680587; called by muse, mutect2, varscan2
- ATP8B1 | c.923G>A p.G308D | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111033609, CM043813, CM980760, COSV99376939; called by muse, mutect2, varscan2
- ATP8B1 | c.623T>C p.V208A | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as rs535998516, COSV99376944; called by muse, varscan2
- ATP8B3 | c.1210G>T p.V404F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.948); catalogued as COSV100034154; called by muse, mutect2, varscan2
- ATP8B3 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | catalogued as COSV100034156; called by muse, mutect2, varscan2
- ATP8B4 | c.1444A>G p.N482D | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99464201; called by muse, mutect2, varscan2
- ATP9A | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as COSV100124477; called by muse, mutect2, varscan2
- ATP9A | c.1356G>A p.M452I | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100124478; called by muse, mutect2, varscan2
- ATR | c.3043C>T p.R1015* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as rs1453839157, COSV99052445; called by muse, mutect2, varscan2
- ATRIP | c.511A>G p.T171A | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV100202694; called by muse, mutect2, varscan2
- ATRN | c.3158A>G p.Y1053C | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.208); catalogued as COSV99496750; called by muse, mutect2, varscan2
- ATRN | c.4165+2T>C p.X1389_splice | Splice Site (SNP) | VAF 26/99 reads (26%) | catalogued as COSV99496753; called by muse, mutect2, varscan2
- ATRNL1 | c.3148G>A p.D1050N | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1554936050, COSV100369626; called by muse, mutect2, varscan2
- ATRX | c.6373A>G p.N2125D | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100970228; called by muse, mutect2, varscan2
- ATRX | c.5386G>A p.D1796N | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100970229; called by muse, mutect2, varscan2
- ATXN1 | c.608A>G p.Q203R | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.012); catalogued as COSV99785487; called by muse, varscan2
- ATXN10 | c.1133T>C p.I378T | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99426100; called by muse, mutect2, varscan2
- ATXN2 | c.2872T>C p.Y958H (on ENST00000550104; = p.Y798H on NM_002973.4) | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV101112626; called by muse, mutect2, varscan2
- ATXN2L | c.396C>T p.G132= | Splice Region (SNP) | VAF 42/134 reads (31%) | catalogued as rs1233525199, COSV100293915; called by muse, mutect2, varscan2
- ATXN2L | c.1013A>G p.E338G | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV100293917; called by muse, mutect2, varscan2
- ATXN7 | c.2306A>G p.N769S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99893931; called by muse, mutect2
- AUTS2 | c.1595A>G p.Q532R | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs759371180, COSV100715448; called by muse, mutect2, varscan2
- AVIL | c.509T>C p.V170A | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV99142208; called by muse, mutect2, varscan2
- AVIL | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV99076242; called by muse, mutect2, varscan2
- AXDND1 | c.1577A>G p.K526R | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100858274; called by muse, mutect2, varscan2
- AXDND1 | c.2135T>C p.L712S | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV100858275; called by muse, mutect2, varscan2
- AXIN2 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs1162424416, COSV100196073; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B2M | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.214); catalogued as COSV100837570; called by muse, mutect2, varscan2
- B3GALT2 | c.220A>T p.T74S | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV100813568; called by muse, mutect2, varscan2
- B3GALT5 | c.392T>C p.L131P | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100563305; called by muse, mutect2, varscan2
- B3GALT5 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100563308; called by muse, mutect2, varscan2
- B3GAT1 | c.242A>G p.D81G | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100437755; called by muse, mutect2, varscan2
- B3GNT3 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59438449; called by muse, mutect2, varscan2
- B3GNT3 | c.791A>G p.Y264C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100427528; called by muse, mutect2, varscan2
- B3GNT5 | c.1112A>G p.Y371C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100191619; called by muse, mutect2, varscan2
- B3GNT9 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.9); PolyPhen benign (0.012); catalogued as COSV99531202; called by muse, mutect2, varscan2
- B4GALNT2 | c.953A>T p.K318M | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100302461; called by muse, mutect2, varscan2
- B4GALNT4 | c.918dup p.R307Afs*98 | Frame Shift Ins (INS) | VAF 22/74 reads (30%) | catalogued as rs770737105; called by mutect2, varscan2
- B4GALNT4 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750624114, COSV100327260; called by muse, mutect2, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 39/66 reads (59%) | catalogued as rs35951843; called by mutect2, varscan2
- B4GALT2 | c.743T>C p.L248P | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV100530650; called by muse, mutect2, varscan2
- B4GALT6 | c.902T>C p.V301A | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV99379820; called by muse, mutect2, varscan2
- BABAM1 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.131); catalogued as COSV99394061; called by muse, mutect2, varscan2
- BACE1 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.341); catalogued as COSV100474880; called by muse, mutect2, varscan2
- BACE2 | c.305del p.P102Rfs*25 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | catalogued as rs771098505; called by mutect2, pindel, varscan2
- BACE2 | c.340A>G p.S114G | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100160599; called by muse, mutect2, varscan2
- BACH1 | c.1001A>G p.D334G | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV99728011; called by muse, mutect2, varscan2
- BAG5 | c.894C>A p.N298K | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.089); catalogued as COSV99914696; called by muse, mutect2, varscan2
- BAG6 | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99276560; called by muse, mutect2, varscan2
- BAHCC1 | c.7748A>G p.N2583S | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100311261; called by muse, mutect2, varscan2
- BAIAP2 | c.1006T>C p.S336P | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.827); catalogued as COSV100347654; called by muse, mutect2, varscan2
- BAIAP2 | c.1577A>G p.N526S | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs1182035051, COSV100352574; called by muse, mutect2, varscan2
- BAIAP2L1 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV99133795; called by muse, mutect2, varscan2
- BANK1 | c.672T>A p.D224E | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100535974; called by muse, mutect2, varscan2
- BANP | c.797C>A p.A266D (on ENST00000286122; = p.A235D on NM_017869.4) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99620975; called by muse, mutect2, varscan2
- BANP | c.1286A>G p.E429G (on ENST00000286122; = p.E401G on NM_079837.3) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV99620979; called by muse, mutect2, varscan2
- BAP1 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99963556; called by muse, mutect2, varscan2
- BAZ1A | c.929A>G p.K310R | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV62410667; called by muse, mutect2, varscan2
- BAZ2B | c.3983del p.K1328Rfs*27 | Frame Shift Del (DEL) | VAF 51/143 reads (36%) | catalogued as rs762040174; called by mutect2, pindel, varscan2
- BAZ2B | c.2777T>C p.M926T | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as rs1359016663, COSV99680881; called by muse, mutect2, varscan2
- BBOF1 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1246270199, COSV67454510; called by muse, mutect2, varscan2
- BBS10 | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); catalogued as COSV99674648; called by muse, mutect2, varscan2
- BBS2 | c.1174G>A p.G392R | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.412); catalogued as COSV99802188; called by muse, mutect2, varscan2
- BBS5 | c.970A>G p.I324V | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1192632212, COSV99751682; called by muse, mutect2, varscan2
- BBS7 | c.926C>T p.T309I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99144837; called by muse, mutect2, varscan2
- BBX | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100361158; called by muse, mutect2, varscan2
- BBX | c.2393A>G p.H798R (on ENST00000325805 / NM_001142568.3; = p.H768R on NM_020235.7) | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100361160; called by muse, mutect2, varscan2
- BBX | c.2614G>A p.D872N (on ENST00000325805 / NM_001142568.3; = p.D842N on NM_020235.7) | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as rs750375871, COSV100361162, COSV100362151; called by muse, mutect2, varscan2
- BCAM | c.132G>A p.M44I | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.353); catalogued as COSV54300742; called by muse, mutect2, varscan2
- BCAN | c.1306A>G p.T436A | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV100227924; called by muse, mutect2, varscan2
- BCAR3 | c.679A>G p.I227V | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV99550384; called by muse, mutect2, varscan2
- BCAS3 | c.668A>T p.Y223F | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as COSV101175443, COSV66783175; called by muse, mutect2, varscan2
- BCAS3 | c.1922A>G p.D641G (on ENST00000390652 / NM_001353144.2; = p.D626G on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs924752071, COSV101175445; called by muse, mutect2, varscan2
- BCAS3 | c.2558A>G p.H853R (on ENST00000390652 / NM_001353144.2; = p.H838R on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV101175448; called by muse, mutect2, varscan2
- BCHE | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as CM074063, COSV100012220; called by muse, mutect2, varscan2
- BCHE | c.661A>G p.T221A | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100012226; called by muse, mutect2, varscan2
- BCL2L1 | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.974); catalogued as COSV100304613, COSV100304618; called by muse, mutect2, varscan2
- BCL2L15 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV100851568; called by muse, mutect2, varscan2
- BCL6B | c.546del p.S183Vfs*20 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | catalogued as COSV53426596; called by mutect2, pindel, varscan2
- BCL9 | c.3890T>C p.V1297A | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.108); catalogued as COSV99324646; called by muse, mutect2, varscan2
- BCLAF3 | c.2015A>G p.Y672C (on ENST00000379682 / NM_001367774.1; = p.Y643C on NM_198279.3) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as rs373927242, COSV100503237; called by muse, varscan2
- BCO1 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); catalogued as COSV50728505; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BCR | c.2117A>G p.H706R | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.029); catalogued as COSV100006107; called by muse, mutect2, varscan2
- BCR | c.3271G>A p.V1091M | Missense Mutation (SNP) | VAF 100/261 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs778229520, COSV100006110; called by muse, mutect2, varscan2
- BEND2 | c.1809T>A p.D603E | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV101191859; called by muse, mutect2, varscan2
- BEND3 | c.1130C>A p.A377D | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.242); catalogued as rs782187458, COSV100944564; called by muse, mutect2, varscan2
- BEND7 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs1261470671, COSV100346457; called by muse, mutect2, varscan2
- BET1 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99747201; called by muse, mutect2, varscan2
- BICD2 | c.337T>C p.Y113H | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.883); catalogued as COSV63548666; called by muse, mutect2, varscan2
- BICDL2 | c.104A>G p.D35G | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs985254500, COSV101199379; called by muse, mutect2, varscan2
- BICRA | c.3269A>G p.K1090R | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.292); catalogued as COSV101194242; called by muse, mutect2
- BIRC6 | c.13126T>C p.Y4376H | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101427969; called by muse, mutect2, varscan2
- BIRC7 | c.682T>C p.W228R | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99416514; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2146A>G p.I716V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as COSV100863631; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2882T>C p.V961A | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs1566469019, COSV100863632; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3419T>C p.V1140A | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV100863635; called by muse, mutect2, varscan2
- BLZF1 | c.280A>G p.N94D | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.021); catalogued as COSV100250517; called by muse, mutect2
- BMP10 | c.472T>C p.Y158H | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as rs1173308256, COSV99770311; called by muse, mutect2, varscan2
- BMP15 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV99399252; called by muse, mutect2, varscan2
- BMP2K | c.2906A>G p.K969R | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.011); catalogued as COSV99784902; called by muse, mutect2, varscan2
- BMP4 | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.219); catalogued as CM091518, COSV99816807; called by muse, mutect2, varscan2
- BMP7 | c.1223A>G p.Y408C | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101215639; called by muse, mutect2, varscan2
- BMP7 | c.1058G>A p.G353D | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101215643, COSV67780686; called by muse, mutect2
- BMP8B | c.746T>C p.V249A | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV100560211; called by muse, mutect2
- BMPR2 | c.2354A>G p.E785G | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101001320; called by muse, mutect2, varscan2
- BMS1 | c.506A>G p.N169S | Missense Mutation (SNP) | VAF 87/285 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs1400615463, COSV100996572; called by muse, mutect2, varscan2
- BMS1 | c.1741C>T p.H581Y | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as rs769940820, COSV100996574; called by muse, mutect2, varscan2
- BMS1 | c.3331A>G p.N1111D | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV100996575; called by muse, mutect2, varscan2
- BNC1 | c.572A>G p.Q191R | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100596967; called by muse, mutect2, varscan2
- BNIPL | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as rs587607488, COSV54845615; called by muse, mutect2, varscan2
- BOD1L1 | c.6322A>G p.T2108A | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1279965602, COSV50008077; called by muse, mutect2, varscan2
- BOD1L1 | c.5866A>G p.S1956G | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99238635; called by muse, mutect2, varscan2
- BOD1L1 | c.5266A>G p.T1756A | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as COSV99238637; called by muse, mutect2, varscan2
- BOD1L1 | c.4692A>G p.I1564M | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV99238639; called by muse, varscan2
- BOD1L1 | c.4561A>G p.T1521A | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99238641; called by muse, varscan2
- BPGM | c.494T>C p.L165P | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100790178; called by muse, mutect2, varscan2
- BPIFA2 | c.739A>G p.T247A | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV99487795; called by muse, varscan2
- BPIFB1 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99487235; called by muse, mutect2, varscan2
- BPIFB2 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as COSV99401223; called by muse, mutect2
- BPNT2 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.526); catalogued as rs1177587665, COSV99388886; called by muse, mutect2, varscan2
- BPTF | c.6959A>G p.Q2320R | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100074320, COSV100074369; called by muse, mutect2, varscan2
- BRCA1 | c.1994A>G p.N665S | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV100523460; called by muse, mutect2
- BRCA2 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101203992; called by muse, mutect2, varscan2
- BRCA2 | c.2213G>A p.C738Y | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1219265131, COSV101203993; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.2938G>A p.D980N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.029); catalogued as COSV101203994, COSV66457349; called by muse, mutect2, varscan2
- BRCA2 | c.3299A>G p.N1100S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as COSV66462970; called by muse, mutect2, varscan2
- BRCA2 | c.5662A>G p.K1888E | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.073); catalogued as COSV101203995; called by muse, mutect2, varscan2
- BRD1 | c.1982T>C p.V661A | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99349352; called by muse, varscan2
- BRD4 | c.1348T>C p.F450L | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99650079; called by muse, mutect2
- BRD4 | c.1346T>C p.V449A | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99650082; called by muse, mutect2
- BRICD5 | c.755C>T p.S252L (on ENST00000562360; = p.S220L on NM_182563.3) | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765416492, COSV57026417, COSV57030922; called by muse, mutect2, varscan2
- BRINP2 | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.358); catalogued as COSV100837898; called by muse, mutect2, varscan2
- BRINP3 | c.1364A>G p.D455G | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV100818454; called by muse, mutect2, varscan2
- BRMS1L | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99396538; called by muse, mutect2, varscan2
- BRMS1L | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV99396539; called by muse, varscan2
- BRPF1 | c.1388A>G p.E463G | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100121133; called by muse, mutect2, varscan2
- BRSK1 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); catalogued as rs369965742; called by muse, varscan2
- BRSK2 | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs1256434246, COSV100372456; called by muse, varscan2
- BRWD3 | c.2359C>T p.R787C | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV64754297; called by muse, mutect2, varscan2
- BSN | c.3377A>G p.Y1126C | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99607574; called by muse, mutect2, varscan2
- BSN | c.10996G>A p.A3666T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1207288882, COSV99607576; called by muse, mutect2, varscan2
- BTAF1 | c.216T>A p.N72K | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as COSV99795030; called by muse, mutect2, varscan2
- BTAF1 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99795035; called by muse, mutect2, varscan2
- BTAF1 | c.5039G>A p.S1680N | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56438463; called by muse, mutect2, varscan2
- BTBD10 | c.616A>G p.T206A | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); catalogued as COSV99533412; called by muse, mutect2, varscan2
- BTBD11 | c.2570A>G p.Y857C (on ENST00000280758 / NM_001018072.2; = p.Y394C on NM_001017523.2) | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV99774952; called by muse, mutect2, varscan2
- BTBD9 | c.1546A>G p.T516A | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.716); catalogued as COSV100021185; called by muse, varscan2
- BTD | c.683T>C p.I228T | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs397514382, CM126830, COSV100329453; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- BTG4 | c.317G>C p.G106A | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766055266, COSV100604391; called by muse, mutect2, varscan2
- BTK | c.393A>G p.V131= | Splice Region (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100437379; called by muse, varscan2
- BTN1A1 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs771506326, COSV55069027; called by muse, mutect2, varscan2
- BTN2A1 | c.967A>G p.T323A | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV100438411; called by muse, mutect2, varscan2
- BTN2A1 | c.1481A>T p.D494V | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV100438414; called by muse, mutect2, varscan2
- BTN3A2 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.172); catalogued as COSV100709582; called by muse, mutect2, varscan2
- BUB1 | c.1454A>G p.D485G | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1417757827, COSV100240994; called by muse, mutect2, varscan2
- C10orf53 | c.470A>G p.Y157C | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.418); catalogued as rs1374149175, COSV100935005; called by muse, mutect2, varscan2
- C10orf71 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.055); catalogued as rs1325284576, COSV100109826; called by muse, mutect2, varscan2
- C11orf40 | n.142-2A>G | Splice Site (SNP) | VAF 24/78 reads (31%) | catalogued as rs201148464; called by muse, varscan2
- C12orf65 | c.373A>G p.S125G | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99473866; called by muse, mutect2, varscan2
- C12orf71 | c.695A>G p.D232G | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.122); catalogued as COSV101460507; called by muse, mutect2, varscan2
- C14orf28 | c.244_245del p.L82Sfs*4 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | catalogued as rs746382141; called by pindel, varscan2
- C14orf28 | c.461A>G p.Y154C | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.634); catalogued as COSV100290086; called by muse, mutect2, varscan2
- C15orf39 | c.1241A>T p.Q414L | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100641223; called by muse, mutect2, varscan2
- C15orf39 | c.2935G>A p.A979T | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.047); catalogued as COSV100641225; called by muse, mutect2, varscan2
- C16orf78 | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV100147589; called by muse, mutect2
- C19orf18 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as COSV100071681; called by muse, mutect2, varscan2
- C19orf44 | c.641A>G p.D214G | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99684962; called by muse, mutect2, varscan2
- C1QA | c.266G>C p.G89A | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101009415; called by muse, mutect2, varscan2
- C1QC | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.059); catalogued as COSV101009416; called by muse, mutect2, varscan2
- C1orf43 | c.334A>G p.T112A (on ENST00000368521 / NM_001297718.2; = p.T78A on NM_015449.4) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV62966972; called by muse, mutect2, varscan2
- C1orf94 | c.620T>C p.V207A (on ENST00000488417 / NM_001134734.2; = p.V17A on NM_032884.5) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV100974759; called by muse, mutect2, varscan2
- C21orf91 | c.554A>G p.N185S | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV99515943; called by muse, mutect2, varscan2
- C2CD2 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs1358381155, COSV100298029; called by muse, mutect2, varscan2
- C2CD3 | c.5638A>C p.T1880P | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100486318; called by muse, mutect2, varscan2
- C2CD3 | c.4475T>G p.I1492S | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100486319; called by muse, mutect2, varscan2
- C2CD3 | c.3925A>G p.S1309G | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.106); catalogued as COSV100486321; called by muse, mutect2, varscan2
8,818 further variants in this file (6,233 protein-altering or splice-affecting, 2,360 silent, 225 other) are not listed here.
